Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6021, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6021-01A (Primary Tumor).

[page 1 of 2]
Pathology Report [REDACTED] **FINAL**

Report Type Pathology Report

Date of Event [REDACTED]

Sex [REDACTED]

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status FINAL

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Laryngeal cancer.

PROCEDURE: Laryngoscopy.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

FINAL DIAGNOSIS:

LARYNGEAL MASS, BIOPSY

INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED, KERATINIZING TYPE.

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received fresh labeled with the patient's name, initials xx and "laryngeal mass for biopsy." It consists of a 1.6 x 0.7 x 0.5 cm aggregate of tan-red soft tissue which is entirely submitted in cassette A.

Grossed by: [REDACTED]

Reviewed by: [REDACTED]

[REDACTED]

Microscopic examination substantiates the above diagnosis.

[REDACTED]

The following statement applies to all immunohistochemistry, Insitu Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation ranges from a minimum of [REDACTED] to a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical

[page 2 of 2]
testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Laryngeal Mass for Bx

Taken:

Stain/cnt Block

HHE x 1 A

H&E x 1 A

Source: NCI Genomic Data Commons file 5220f20f-7c0a-423b-bef9-770543935b2a (TCGA-CN-6021.0868D82E-33A9-419D-8471-79C3D16FA00B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).